RC case RC-B6VM — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8a7810d-5c23-4cfb-87fd-a4b86ecd5eae

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1963; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 58.9 years (21,510 days); Year of diagnosis: 2022; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph node, NOS / Lymph Node, Mesenteric / Bone marrow / Leptomeninges / Lung, NOS.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 1.4 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 10 days; Number of cycles: 3; Treatment outcome: Treatment Ongoing; Timepoint category: First Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Ongoing; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 77, day 84.

Molecular and laboratory tests
- Lactate Dehydrogenase 607 U/L [Blood test normal range upper: 220].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Anemia.
- Timepoint category: Initial Diagnosis; Weight: 70.9 kg; Height: 175.3 cm; BMI: 23.1.
- Timepoint category: Prior to Diagnosis; Risk factors: Anemia.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples)
- Sample RC-B6VM-NB1-A: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B6VM-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
